Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A702, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A702-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology	Final Results
--------------------	---------------

Surgical Pathology

Final

CASE NUMBER:

DIAGNOSIS:

1. Soft tissue, paracaval node, resection: Lymph nodes, no tumor seen (0/4).

2. Soft tissue, right retroperitoneal mass, resection: Paraganglioma (extraadrenal pheochromocytoma).

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the Laboratory of Pathology. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Allocate Order to Protocol: Brief

Clinical History:

Paraganglioma, para caval Right Specimen Taken For
Protocol: 01 - Yes

PROCEDURE: Pre-Operative Diagnosis: Paraganglioma, para caval Right

Post-Operative Diagnosis: Paraganglioma, para caval Right Operative

Findings: Paraganglioma, para caval Right

SPECIMENS SUBMITTED: 1. LYMPH NODES, Paracaval
2. LYMPH NODES, Right retroperineal paraganglioma

GROSS DESCRIPTION: Received are 2 containers labeled with the patient's name, medical record number and further specified as:

1. "Paracaval node" consists of a piece of yellow-tan soft tissue fragment measuring 2.1 x 1.0 x 0.5 cm. The specimen is entirely submitted in white cassette labeled for permanent processing.

2. "Right retroperitoneal paraganglioma" consists of pink-yellow-tan soft tissue mass weighing 19.2 grams, measuring 4.5 x 3.5 x 1.2 cm. The specimen is already opened. The outer surface is inked in black. The opened area is inked in green. The cut surface shows a variegated, pink-yellow-tan necrosis. Approximately 40% of the tissue is procured for

The procurement was performed by

In Surgical Pathology, the specimen received matches the above description. The specimen is serially sectioned and representative sections are submitted in white cassettes labeled

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974

Requested By:

Do not file in Medical Record

[page 2 of 2]
Surgical Pathology

Final Results

for permanent processing.

Gross Description dictated by

No consultants

#

#

HPA Discrepancy		✓

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

Requested By:

Do not file in Medical Record

Source: NCI Genomic Data Commons file 3c04c0e5-f5ba-49f7-89b6-ea9f672845f4 (TCGA-QR-A702.EA5D8EC1-2095-457E-9492-6BCE3E6A6E73.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).